Surgical pathology report (de-identified scan), TCGA case TCGA-CH-5764, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CH-5764-01A (Primary Tumor).

Diagnosis

1. Poorly differentiated bilateral adenocarcinoma of the prostate across the organ, mainly in the peripheral zone (Gleason 4+3=7, tertiary grade 5). Gleason 4: 5%, Gleason 5: <5%. Max. tumor diameter 31 mm. Tumor infiltration of rectolateral periprostatic fatty tissue on both sides in three successive steps (infiltration depth up to 1.5 mm, infiltration width up to 6 mm). Bilateral infiltration of seminal vesicles. Extensive tumor involvement of perineural sheaths.

Tumor-free surgical preparation margins.

Additional foci of a prostatic intraepithelial neoplasia (HGPIN) and signs of myoglandular prostatic hyperplasia. Urothelium of prostatic urethra without dysplasia.

2. Five tumor-free lymph nodes on the right (0/5).
3. Three tumor-free lymph nodes on the left (0/3).

Tumor classification

pT3b, max. tumor diameter 31 mm. Gleason 4+3=7, tertiary grade 5 (Gleason 4: 70%, Gleason 5: <5%), R0, pN0 (0/8)

Remark

No further carcinoma was detected in the prior frozen section analysis.

Carcinoma tissue was detected in the punch biopsies. Here, too, a Gleason 4 pattern was predominant. Gleason 5 patterns were not observed.

Follow-up report

Immunohistology: D2-40, CD31 (BR1, BR2).

Additional immunohistological investigations were carried out to establish whether there was vessel invasion. No evidence of either lymph or blood vessel invasion was detected.

Final tumor classification:

pT3b, maximum tumor diameter 31.0 mm, Gleason 4+3=7 tertiary grade 5 (Gleason 4: 70%, Gleason 5: < 5%), L0, V0, R0, pN0 (0/8).

Source: NCI Genomic Data Commons file 8694c2dc-2d53-490b-937d-1715a1a0d43a (TCGA-CH-5764.E7F4FCEB-1960-44F0-8E0B-FDE2337011CE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).